CPTAC case SC-0085 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cfb3587b-e291-465f-9bf7-6e271ac3e1ee

Demographics
Sex at birth: male; Vital status: Dead; Days to death: 122 days.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin of upper limb and shoulder; Age at diagnosis: 69.0 years (25,202 days); AJCC staging edition: 8th; AJCC pathologic T: T4a; AJCC pathologic N: N3b; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Progression or recurrence: no; Clark level: V.
   Pathology details: Breslow thickness: 13.

Biospecimens (1 sample)
- Sample S-1609-003719: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Frozen; Initial weight: 119 mg; Method of sample procurement: Tumor Resection.
